Somatic mutation profile of tumor specimen TCGA-85-8071-01A (aliquot TCGA-85-8071-01A-11D-2244-08) from TCGA case TCGA-85-8071, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.5 years (19,158 days).
Specimen TCGA-85-8071-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1523de32-ff98-4683-8668-09e4308d1e31.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-85-8071-10A (Blood Derived Normal), aliquot TCGA-85-8071-10A-01D-2244-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f0a087bd-b0ed-45a3-be1c-3e28be3f88ce

The open-access MAF lists 400 somatic variants for this specimen: 289 protein-altering or splice-affecting, 94 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 244, Silent 94, Nonsense Mutation 18, Splice Site 14, Intron 10, Splice Region 6, Frame Shift Del 5, RNA 4, Frame Shift Ins 2, 5'UTR 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.375G>A p.T125= | Splice Region (SNP) | VAF 24/37 reads (65%) | catalogued as rs55863639, CS004351, CS011573, CS971913, COSV52665709, COSV52718605, COSV52726641, COSV53120615; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AASDH | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 36/82 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.759); catalogued as COSV99221137; called by muse, mutect2
- AC006059.2 | c.2044G>C p.E682Q | Missense Mutation (SNP) | VAF 55/68 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV100045450; called by muse, mutect2, varscan2
- ACAP3 | c.463G>T p.G155W | Missense Mutation (SNP) | VAF 8/12 reads (67%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.814); catalogued as COSV100686302; called by muse, mutect2, varscan2
- ADAM28 | c.2167C>A p.Q723K | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV56106914, COSV99738451; called by muse, varscan2
- ADAM7 | c.808C>G p.R270G | Missense Mutation (SNP) | VAF 17/47 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.098); catalogued as COSV99443703; called by muse, mutect2
- ADAMTS16 | c.3353C>T p.P1118L | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0.05); PolyPhen benign (0.058); catalogued as COSV99940903; called by muse, mutect2, varscan2
- ADAMTSL3 | c.392G>T p.R131I | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99718317; called by muse, mutect2, varscan2
- ADGRB3 | c.4196C>A p.S1399* | Nonsense Mutation (SNP) | VAF 68/90 reads (76%) | catalogued as COSV99484691; called by muse, mutect2, varscan2
- ADGRD1 | c.97C>G p.H33D | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.446); catalogued as COSV99895023; called by muse, mutect2, varscan2
- ADGRE2 | c.181C>A p.P61T | Missense Mutation (SNP) | VAF 64/173 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as COSV100215934; called by muse, mutect2, varscan2
- ADHFE1 | c.316G>T p.V106F | Missense Mutation (SNP) | VAF 113/308 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.865); catalogued as COSV99397776; called by muse, mutect2, varscan2
- AHNAK2 | c.3133G>A p.D1045N | Missense Mutation (SNP) | VAF 40/502 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.63); catalogued as COSV100317072; called by muse, mutect2
- ALOX15B | c.1058G>C p.W353S | Missense Mutation (SNP) | VAF 51/113 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101205605; called by muse, mutect2, varscan2
- ANK2 | c.10260G>T p.R3420S | Missense Mutation (SNP) | VAF 19/64 reads (30%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV100001090; called by muse, mutect2, varscan2
- ANKS1B | c.3134T>C p.V1045A (on ENST00000547776 / NM_152788.4; = p.V211A on NM_020140.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV100227747; called by muse, mutect2, varscan2
- ANO5 | c.68A>T p.Y23F | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.65); PolyPhen benign (0); catalogued as COSV100201725; called by muse, mutect2, varscan2
- ANO5 | c.701G>C p.R234T | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.11); catalogued as COSV100201748, COSV61086066; called by muse, mutect2, varscan2
- ANXA5 | c.532G>A p.A178T | Missense Mutation (SNP) | VAF 16/34 reads (47%) | SIFT tolerated (0.5); PolyPhen benign (0.001); catalogued as COSV99634317; called by muse, mutect2, varscan2
- AOC3 | c.1835G>A p.G612E | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs923917859, COSV99520107; called by muse, mutect2, varscan2
- ARHGAP26 | c.1395G>T p.M465I | Missense Mutation (SNP) | VAF 61/92 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99190815; called by muse, mutect2, varscan2
- ARHGEF16 | c.873G>T p.E291D | Missense Mutation (SNP) | VAF 26/34 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV101000405; called by muse, mutect2, varscan2
- ASPM | c.7738A>T p.T2580S | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.459); catalogued as COSV99660144; called by muse, mutect2, varscan2
- ASPM | c.6968G>A p.R2323K | Missense Mutation (SNP) | VAF 25/61 reads (41%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.823); catalogued as COSV54134434, COSV99660145; called by muse, mutect2, varscan2
- ATP10A | c.1418C>A p.P473H | Missense Mutation (SNP) | VAF 11/22 reads (50%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as COSV100791122; called by muse, mutect2, varscan2
- B4GALNT1 | c.1520C>T p.P507L | Missense Mutation (SNP) | VAF 61/159 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); catalogued as rs766285396, COSV100247076; called by muse, mutect2, varscan2
- BDP1 | c.596T>G p.M199R | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100702968; called by muse, mutect2, varscan2
- BPGM | c.269G>A p.R90H | Missense Mutation (SNP) | VAF 16/28 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs781222092, CM149154, COSV61324084; called by muse, mutect2, varscan2
- BRCA1 | c.3730C>A p.H1244N | Missense Mutation (SNP) | VAF 36/116 reads (31%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV100523933, COSV58803363; called by muse, mutect2, varscan2
- BRINP3 | c.1061G>A p.R354H | Missense Mutation (SNP) | VAF 57/132 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs778586472, COSV66525489; called by muse, mutect2, varscan2
- BRSK2 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV57550094; called by muse, mutect2, varscan2
- C5 | c.1502A>G p.Y501C | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99797688; called by muse, mutect2, varscan2
- C5orf22 | c.133A>T p.N45Y | Missense Mutation (SNP) | VAF 18/99 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.924); catalogued as COSV100323454, COSV57599222; called by muse, mutect2, varscan2
- CACYBP | c.573G>C p.L191F | Missense Mutation (SNP) | VAF 8/14 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100871533; called by muse, mutect2, varscan2
- CADM2 | c.446C>T p.S149F (on ENST00000407528 / NM_001167674.2; = p.S151F on NM_153184.4) | Missense Mutation (SNP) | VAF 12/18 reads (67%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.897); catalogued as COSV101054517, COSV67405972; called by muse, mutect2, varscan2
- CASKIN2 | c.196G>T p.A66S | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100395348; called by muse, mutect2, varscan2
- CCDC141 | c.3075C>A p.Y1025* | Nonsense Mutation (SNP) | VAF 23/53 reads (43%) | catalogued as COSV99836649; called by muse, mutect2, varscan2
- CCDC181 | c.1120A>G p.I374V | Missense Mutation (SNP) | VAF 12/32 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV100890306; called by muse, mutect2, varscan2
- CCDC40 | c.2464G>T p.E822* | Nonsense Mutation (SNP) | VAF 8/18 reads (44%) | catalogued as rs752301491, COSV66475779; called by muse, mutect2, varscan2
- CDCA8 | c.798+1G>T p.X266_splice | Splice Site (SNP) | VAF 22/76 reads (29%) | catalogued as COSV100523564; called by muse, mutect2, varscan2
- CDIP1 | c.85+1G>A p.X29_splice | Splice Site (SNP) | VAF 9/18 reads (50%) | catalogued as COSV99566500; called by muse, mutect2, varscan2
- CDKN2A | c.248A>T p.H83L | Missense Mutation (SNP) | VAF 19/27 reads (70%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58689512, COSV58690350, COSV58703585; called by muse, mutect2, varscan2
- CEACAM5 | c.1440T>A p.N480K | Missense Mutation (SNP) | VAF 15/20 reads (75%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.723); catalogued as COSV99703862; called by muse, mutect2, varscan2
- CENPE | c.7358A>T p.Y2453F | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.575); catalogued as COSV99477664; called by muse, varscan2
- CFHR5 | c.1292G>T p.C431F | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99888517; called by muse, mutect2, varscan2
- CHRD | c.2528C>T p.P843L | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV99200372; called by muse, mutect2, varscan2
- CHST10 | c.104A>G p.Y35C | Missense Mutation (SNP) | VAF 25/72 reads (35%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV99958896; called by muse, mutect2, varscan2
- CNBP | c.32G>T p.R11L | Missense Mutation (SNP) | VAF 16/37 reads (43%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.591); catalogued as COSV101421472; called by muse, mutect2, varscan2
- CNGB3 | c.1082T>G p.L361R | Missense Mutation (SNP) | VAF 29/78 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100181801; called by muse, mutect2, varscan2
- COL4A5 | c.3996A>T p.P1332= | Splice Region (SNP) | VAF 12/12 reads (100%) | catalogued as COSV100087432; called by muse, mutect2, varscan2
- COLGALT2 | c.580G>T p.E194* | Nonsense Mutation (SNP) | VAF 35/89 reads (39%) | catalogued as COSV100730579; called by muse, mutect2, varscan2
- COPB1 | c.1825G>A p.D609N | Missense Mutation (SNP) | VAF 21/54 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.517); catalogued as COSV99999492; called by muse, mutect2, varscan2
- CSMD1 | c.3721G>C p.V1241L (on ENST00000520002; = p.V1240L on NM_033225.6) | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.119); catalogued as rs1442544858, COSV100146863; called by muse, mutect2, varscan2
- CTH | c.251-1G>A p.X84_splice | Splice Site (SNP) | VAF 16/47 reads (34%) | catalogued as rs28498802, COSV100697069; called by muse, mutect2, varscan2
- CX3CR1 | c.379A>T p.R127W | Missense Mutation (SNP) | VAF 30/45 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100843179; called by muse, mutect2, varscan2
- DCDC1 | c.4325C>A p.T1442K (on ENST00000597505 / NM_001367979.1; = p.T549K on NM_020869.3) | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.278); catalogued as COSV100338122; called by muse, varscan2
- DCHS1 | c.8407G>C p.V2803L | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV100197357; called by muse, mutect2, varscan2
- DCHS1 | c.6233G>T p.R2078L | Missense Mutation (SNP) | VAF 14/34 reads (41%) | SIFT tolerated (0.12); PolyPhen benign (0.1); catalogued as rs144463486, COSV55036699; called by muse, mutect2, varscan2
- DCN | c.83T>A p.M28K | Missense Mutation (SNP) | VAF 16/38 reads (42%) | SIFT deleterious (0.01); PolyPhen benign (0.266); catalogued as COSV99272046; called by muse, mutect2, varscan2
- DDHD1 | c.2017G>A p.D673N (on ENST00000323669; = p.D870N on NM_030637.3) | Missense Mutation (SNP) | VAF 40/53 reads (75%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.76); catalogued as COSV60361830; called by muse, mutect2, varscan2
- DEF6 | c.899G>A p.R300H | Missense Mutation (SNP) | VAF 16/18 reads (89%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100359260; called by muse, mutect2, varscan2
- DEPDC5 | c.2381T>C p.V794A (on ENST00000400246; = p.V863A on NM_014662.5) | Missense Mutation (SNP) | VAF 39/94 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV99835105; called by muse, mutect2, varscan2
- DGKI | c.1564-1G>A p.X522_splice | Splice Site (SNP) | VAF 40/43 reads (93%) | catalogued as COSV99933787; called by muse, mutect2, varscan2
- DNAH5 | c.4613C>A p.A1538E | Missense Mutation (SNP) | VAF 84/175 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99444675, COSV99448650; called by muse, mutect2, varscan2
- DNAI2 | c.904G>A p.E302K | Missense Mutation (SNP) | VAF 82/193 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.788); catalogued as COSV56758212; called by muse, mutect2, varscan2
- DOK6 | c.737G>T p.R246L | Missense Mutation (SNP) | VAF 28/43 reads (65%) | SIFT deleterious (0.02); PolyPhen benign (0.14); catalogued as COSV66933129, COSV66938262; called by muse, mutect2, varscan2
- DSCAML1 | c.1925A>T p.Q642L (on ENST00000321322; = p.Q582L on NM_020693.4) | Missense Mutation (SNP) | VAF 19/25 reads (76%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.81); catalogued as COSV100355645; called by muse, mutect2, varscan2
- DYNC2H1 | c.3783A>C p.R1261S | Missense Mutation (SNP) | VAF 13/19 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100518279; called by muse, mutect2, varscan2
- DYNC2H1 | c.7411G>T p.G2471* | Nonsense Mutation (SNP) | VAF 46/60 reads (77%) | catalogued as COSV100518280; called by muse, mutect2, varscan2
- EFNA1 | c.566C>A p.P189Q | Missense Mutation (SNP) | VAF 24/70 reads (34%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.997); catalogued as COSV100310316, COSV100310381; called by muse, mutect2, varscan2
- EIF5 | c.1153G>A p.A385T | Missense Mutation (SNP) | VAF 45/236 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV99384750; called by muse, mutect2, varscan2
- EPRS1 | c.2537C>T p.P846L | Missense Mutation (SNP) | VAF 58/144 reads (40%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV65098819; called by muse, mutect2, varscan2
- FAM135B | c.410C>A p.T137K | Missense Mutation (SNP) | VAF 111/315 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV50521953, COSV99356912; called by muse, mutect2, varscan2
- FAM8A1 | c.958-1del p.X320_splice | Splice Site (DEL) | VAF 43/68 reads (63%) | catalogued as COSV99467501; called by mutect2, pindel, varscan2
- FAP | c.971G>A p.R324K | Missense Mutation (SNP) | VAF 97/222 reads (44%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs1344855962, COSV51868095; called by muse, mutect2, varscan2
- FARSB | c.786G>A p.K262= | Splice Region (SNP) | VAF 10/56 reads (18%) | catalogued as COSV99918311; called by muse, mutect2, varscan2
- FAT3 | c.6425A>G p.K2142R | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.006); catalogued as COSV99965068; called by muse, mutect2
- FBXO42 | c.5C>G p.A2G | Missense Mutation (SNP) | VAF 17/18 reads (94%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.096); catalogued as COSV100981725; called by muse, mutect2, varscan2
- FCGR2C | c.941C>T p.P314L | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.849); catalogued as COSV100912696; called by muse, mutect2, varscan2
- FN1 | c.5221C>A p.Q1741K | Missense Mutation (SNP) | VAF 47/89 reads (53%) | SIFT tolerated (0.97); PolyPhen benign (0.007); catalogued as COSV100116909; called by muse, mutect2, varscan2
- FNDC1 | c.2267A>G p.N756S | Missense Mutation (SNP) | VAF 72/98 reads (73%) | SIFT tolerated, low confidence (0.42); PolyPhen benign (0.026); catalogued as rs755290240, COSV99795584; called by muse, mutect2, varscan2
- FOCAD | c.724G>C p.E242Q | Missense Mutation (SNP) | VAF 30/39 reads (77%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV100620298; called by muse, mutect2, varscan2
- FSCB | c.2293G>A p.V765M | Missense Mutation (SNP) | VAF 150/168 reads (89%) | SIFT tolerated (0.06); PolyPhen benign (0.392); catalogued as rs1293814314, COSV100469212; called by muse, mutect2, varscan2
- FSCB | c.283G>T p.E95* | Nonsense Mutation (SNP) | VAF 94/109 reads (86%) | catalogued as COSV100469214, COSV61217375; called by muse, mutect2, varscan2
- GAB4 | c.172T>C p.F58L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.418); catalogued as COSV101271959; called by mutect2, varscan2
- GBA | c.1280A>T p.E427V | Missense Mutation (SNP) | VAF 17/36 reads (47%) | SIFT deleterious (0.05); PolyPhen benign (0.081); catalogued as COSV100516323; called by muse, mutect2, varscan2
- GDF9 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 30/46 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51525820; called by muse, mutect2, varscan2
- GLIS1 | c.995G>T p.R332L | Missense Mutation (SNP) | VAF 61/149 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.348); catalogued as rs201662227, COSV100389850, COSV56546409; called by muse, mutect2, varscan2
- GLT1D1 | c.707A>T p.H236L (on ENST00000442111 / NM_001366889.1; = p.H156L on NM_144669.3) | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as COSV99896465; called by muse, mutect2, varscan2
- GPATCH2 | c.1514G>C p.G505A | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100861690; called by muse, mutect2, varscan2
- GPATCH8 | c.2306A>C p.K769T | Missense Mutation (SNP) | VAF 58/113 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.115); catalogued as COSV100132604; called by muse, mutect2, varscan2
- GPR141 | c.449T>C p.L150P | Missense Mutation (SNP) | VAF 91/113 reads (81%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100550295; called by muse, mutect2, varscan2
- GPR142 | c.1163G>A p.R388Q | Missense Mutation (SNP) | VAF 44/144 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.097); catalogued as rs367783578; called by muse, mutect2
- GPSM1 | c.925G>T p.A309S | Missense Mutation (SNP) | VAF 6/13 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.433); catalogued as COSV100696590; called by muse, varscan2
- GRXCR1 | c.85C>G p.L29V | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV101295654, COSV67670157; called by muse, mutect2, varscan2
- GTF2A1 | c.491A>T p.Q164L | Missense Mutation (SNP) | VAF 44/47 reads (94%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99993392; called by muse, mutect2, varscan2
- H1-4 | c.46G>T p.E16* | Nonsense Mutation (SNP) | VAF 123/149 reads (83%) | catalogued as COSV56803254, COSV56803481; called by muse, mutect2, varscan2
- HBS1L | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 46/53 reads (87%) | SIFT tolerated (0.48); PolyPhen benign (0.33); catalogued as rs562783458, COSV100892544; called by muse, mutect2, varscan2
- HTR1A | c.634C>A p.L212M | Missense Mutation (SNP) | VAF 69/109 reads (63%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV100109033; called by muse, mutect2, varscan2
- IFNA10 | c.497T>C p.V166A | Missense Mutation (SNP) | VAF 139/216 reads (64%) | SIFT deleterious (0); PolyPhen possibly damaging (0.488); catalogued as rs777708143, COSV53331140, COSV53331423, COSV99497451; called by muse, mutect2, varscan2
- IGFN1 | c.2179G>T p.A727S (on ENST00000295591 / NM_001367841.1; = p.A3184S on NM_001164586.2) | Missense Mutation (SNP) | VAF 45/113 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.009); catalogued as rs746779670, COSV99811980; called by muse, mutect2, varscan2
- IGHV3-33 | c.140C>A p.T47N | Missense Mutation (SNP) | VAF 243/436 reads (56%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.03); catalogued as rs187304239; called by muse, mutect2, varscan2
- IKZF1 | c.325G>A p.G109S | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV100498321; called by muse, mutect2, varscan2
- IQGAP1 | c.1832G>T p.W611L | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99184953; called by muse, mutect2, varscan2
- IQGAP1 | c.1833G>T p.W611C | Missense Mutation (SNP) | VAF 30/128 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.027); catalogued as COSV99184954; called by muse, mutect2, varscan2
- IRX1 | c.429G>T p.K143N | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100116422; called by muse, mutect2, varscan2
- ITGA3 | c.2525G>T p.G842V | Missense Mutation (SNP) | VAF 51/140 reads (36%) | SIFT tolerated (0.14); PolyPhen benign (0.243); catalogued as COSV99143536; called by muse, mutect2, varscan2
- ITM2A | c.322T>A p.F108I | Missense Mutation (SNP) | VAF 14/14 reads (100%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.654); catalogued as COSV100964443; called by muse, mutect2, varscan2
- KCNJ3 | c.315C>G p.I105M | Missense Mutation (SNP) | VAF 28/67 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV54543863, COSV99715652; called by muse, mutect2, varscan2
- KCNN2 | c.403A>T p.S135C (on ENST00000264773; = p.S347C on NM_021614.4) | Missense Mutation (SNP) | VAF 23/26 reads (88%) | SIFT deleterious (0.05); PolyPhen probably damaging (1); catalogued as COSV99299484; called by muse, mutect2, varscan2
- KIAA1109 | c.10390A>G p.I3464V | Missense Mutation (SNP) | VAF 117/246 reads (48%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.891); catalogued as COSV99155061; called by muse, mutect2, varscan2
- KIF26B | c.4148G>T p.G1383V | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as COSV100832152; called by muse, mutect2, varscan2
- KLHL1 | c.2116G>T p.G706C | Missense Mutation (SNP) | VAF 37/52 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100917156; called by muse, mutect2, varscan2
- KY | c.448C>A p.Q150K | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV101414974; called by muse, mutect2, varscan2
- L3MBTL3 | c.269C>G p.S90C | Missense Mutation (SNP) | VAF 36/98 reads (37%) | SIFT tolerated (0.08); PolyPhen benign (0.19); catalogued as COSV100695969; called by muse, mutect2, varscan2
- LGMN | c.234A>C p.E78D | Missense Mutation (SNP) | VAF 83/337 reads (25%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as COSV100605795; called by muse, mutect2, varscan2
- LRBA | c.6482-1G>C p.X2161_splice | Splice Site (SNP) | VAF 20/51 reads (39%) | catalogued as COSV100841400; called by muse, mutect2, varscan2
- LRRC7 | c.2107+1G>A p.X703_splice (on ENST00000651989 / NM_001370785.2; = p.X670_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 11/32 reads (34%) | catalogued as rs1344591005, COSV99225564; called by muse, mutect2, varscan2
- LRTM2 | c.913A>G p.R305G | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99765500; called by muse, mutect2, varscan2
- LY75-CD302 | c.5307T>A p.C1769* | Nonsense Mutation (SNP) | VAF 18/26 reads (69%) | catalogued as COSV99374427; called by muse, mutect2, varscan2
- MACO1 | c.818A>G p.N273S | Missense Mutation (SNP) | VAF 14/23 reads (61%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs1190646046, COSV100975128; called by muse, mutect2, varscan2
- MAGEL2 | c.3488G>A p.R1163K | Missense Mutation (SNP) | VAF 6/24 reads (25%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.319); catalogued as COSV100045886; called by muse, mutect2, varscan2
- MAGI2 | c.3218T>A p.V1073E | Missense Mutation (SNP) | VAF 43/49 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100834171; called by muse, mutect2, varscan2
- MAGI2 | c.419G>T p.C140F | Missense Mutation (SNP) | VAF 14/16 reads (88%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100834173; called by muse, mutect2, varscan2
- MGAM | c.854T>C p.I285T | Missense Mutation (SNP) | VAF 78/93 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV101516406; called by muse, mutect2, varscan2
- MKI67 | c.8920G>T p.V2974L | Missense Mutation (SNP) | VAF 20/51 reads (39%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100896430, COSV64076808; called by muse, mutect2, varscan2
- MMRN1 | c.3421T>A p.Y1141N | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99306985; called by muse, mutect2, varscan2
- MYH1 | c.2740A>T p.K914* | Nonsense Mutation (SNP) | VAF 20/74 reads (27%) | catalogued as COSV99875645; called by muse, mutect2, varscan2
- MYH11 | c.2494T>A p.W832R | Missense Mutation (SNP) | VAF 58/68 reads (85%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100258617; called by muse, mutect2, varscan2
- MYO1H | c.1945C>G p.Q649E | Missense Mutation (SNP) | VAF 59/190 reads (31%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.686); catalogued as rs754158430, COSV100183424; called by muse, mutect2, varscan2
- MYOCD | c.646C>A p.H216N | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.99); PolyPhen benign (0); catalogued as COSV100590627, COSV99060680; called by muse, mutect2, varscan2
- NAA15 | c.1548A>G p.I516M | Missense Mutation (SNP) | VAF 17/30 reads (57%) | SIFT tolerated (0.14); PolyPhen benign (0.197); catalogued as COSV99649473; called by muse, mutect2, varscan2
- NCKAP1L | c.2107A>G p.I703V | Missense Mutation (SNP) | VAF 28/68 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0.006); catalogued as rs1285126908, COSV99514927; called by muse, mutect2, varscan2
- NDST4 | c.1536A>T p.P512= | Splice Region (SNP) | VAF 26/65 reads (40%) | catalogued as COSV99996211; called by muse, mutect2, varscan2
- NLRP14 | c.2842G>T p.D948Y | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.979); catalogued as COSV100204863; called by muse, mutect2, varscan2
- NLRP5 | c.124C>A p.Q42K | Missense Mutation (SNP) | VAF 5/48 reads (10%) | SIFT tolerated (0.48); PolyPhen benign (0.017); catalogued as COSV101173595; called by muse, mutect2, varscan2
- NLRP8 | c.1709C>G p.A570G | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.379); catalogued as COSV99405142; called by muse, mutect2, varscan2
- NMUR2 | c.1004A>T p.Q335L | Missense Mutation (SNP) | VAF 53/78 reads (68%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as COSV99676825; called by muse, mutect2, varscan2
- NOSTRIN | c.1400T>C p.I467T (on ENST00000317647 / NM_001039724.4; = p.I389T on NM_052946.3) | Missense Mutation (SNP) | VAF 24/51 reads (47%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.828); catalogued as rs1161662685, COSV100473429; called by muse, mutect2, varscan2
- NRXN3 | c.894C>A p.H298Q | Missense Mutation (SNP) | VAF 21/29 reads (72%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as COSV100203076; called by muse, mutect2, varscan2
- NSD1 | c.5084C>T p.P1695L | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as rs756456036, COSV100728857; called by muse, mutect2, varscan2
- NSUN6 | c.1072-1G>T p.X358_splice | Splice Site (SNP) | VAF 10/12 reads (83%) | catalogued as COSV101045566, COSV66032349; called by muse, mutect2
- NUAK2 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs763336598, COSV100904031; called by muse, mutect2, varscan2
- OBSCN | c.16516G>T p.D5506Y | Missense Mutation (SNP) | VAF 49/150 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV99476690; called by muse, mutect2, varscan2
- OR10K1 | c.8A>T p.Q3L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen benign (0.013); catalogued as COSV99193463; called by muse, mutect2, varscan2
- OR10X1 | c.930G>T p.M310I | Missense Mutation (SNP) | VAF 37/112 reads (33%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV100936633, COSV63766869; called by muse, mutect2, varscan2
- OR10X1 | c.929T>A p.M310K | Missense Mutation (SNP) | VAF 37/109 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.261); catalogued as COSV100936635; called by muse, mutect2, varscan2
- OR13F1 | c.466G>A p.A156T | Missense Mutation (SNP) | VAF 57/147 reads (39%) | SIFT deleterious (0.04); PolyPhen benign (0.17); catalogued as rs1227551226, COSV100594738; called by muse, mutect2, varscan2
- OR14I1 | c.841C>T p.P281S | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.951); catalogued as COSV100700469; called by muse, mutect2, varscan2
- OR1J1 | c.539A>T p.D180V | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV99403128; called by muse, varscan2
- OR51G2 | c.914G>T p.R305L | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV58991743, COSV58993153; called by muse, mutect2, varscan2
- OR51Q1 | c.25C>G p.Q9E | Missense Mutation (SNP) | VAF 49/132 reads (37%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100332903, COSV56180837; called by muse, mutect2, varscan2
- OR52E8 | c.587C>A p.A196D | Missense Mutation (SNP) | VAF 53/118 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.236); catalogued as COSV101190169, COSV66205626; called by muse, mutect2, varscan2
- OR5D13 | c.586A>C p.I196L | Missense Mutation (SNP) | VAF 61/108 reads (56%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV100686837; called by muse, mutect2, varscan2
- OR7D2 | c.93C>A p.F31L | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as COSV100712992; called by muse, mutect2, varscan2
- OR8K1 | c.29C>A p.T10K | Missense Mutation (SNP) | VAF 38/119 reads (32%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.007); catalogued as COSV54401974; called by muse, mutect2
- OSBPL5 | c.1522+1G>T p.X508_splice | Splice Site (SNP) | VAF 21/47 reads (45%) | catalogued as COSV99720309; called by muse, mutect2, varscan2
- PAPPA | c.985C>A p.Q329K | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.968); catalogued as COSV100073760, COSV100075654; called by muse, mutect2, varscan2
- PAX8 | c.612T>G p.D204E | Missense Mutation (SNP) | VAF 21/63 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99639396; called by muse, mutect2, varscan2
- PCDH11Y | c.3706C>T p.L1236F | Missense Mutation (SNP) | VAF 40/51 reads (78%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.159); catalogued as COSV99291206; called by muse, mutect2, varscan2
- PCDH15 | c.4844G>T p.R1615L (on ENST00000644397 / NM_001354429.2; = p.R1557L on NM_001142771.2) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as rs1161120610, COSV100903867, COSV64702290; called by muse, mutect2, varscan2
- PCNX2 | c.1192G>T p.V398L | Missense Mutation (SNP) | VAF 32/84 reads (38%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0); catalogued as COSV99267087; called by muse, mutect2, varscan2
- PDE6C | c.1772A>G p.E591G | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.859); catalogued as COSV101008693, COSV65117575; called by muse, mutect2, varscan2
- PDGFRL | c.448G>T p.G150C | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs750440858, COSV99286306; called by muse, mutect2, varscan2
- PGM5 | c.1357C>G p.L453V | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as COSV101123890; called by muse, mutect2, varscan2
- PIAS3 | c.984G>T p.P328= | Splice Region (SNP) | VAF 15/43 reads (35%) | catalogued as COSV100566773; called by muse, mutect2, varscan2
- PIDD1 | c.2479G>T p.D827Y | Missense Mutation (SNP) | VAF 12/23 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100204178; called by muse, mutect2, varscan2
- PIKFYVE | c.5636T>C p.M1879T | Missense Mutation (SNP) | VAF 43/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV100010476; called by muse, mutect2, varscan2
- PITPNM3 | c.913G>A p.A305T | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.46); PolyPhen benign (0.009); catalogued as rs549384558, COSV99338272; called by muse, mutect2, varscan2
- PKD2L1 | c.735G>T p.W245C | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100559358; called by muse, mutect2, varscan2
- PKHD1L1 | c.23G>A p.G8D | Missense Mutation (SNP) | VAF 9/28 reads (32%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.041); catalogued as rs1439123304, COSV101005994; called by muse, mutect2
- PLCL1 | c.460G>C p.E154Q | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.755); catalogued as COSV101406880; called by muse, mutect2, varscan2
- PLCL1 | c.2732T>C p.I911T | Missense Mutation (SNP) | VAF 266/649 reads (41%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV101406882; called by muse, varscan2
- PLXNA4 | c.997G>C p.D333H | Missense Mutation (SNP) | VAF 46/56 reads (82%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV100323836, COSV58149653, COSV58164095; called by muse, mutect2, varscan2
- PLXNB2 | c.4853C>G p.T1618S | Missense Mutation (SNP) | VAF 23/45 reads (51%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.985); catalogued as COSV100834018; called by muse, mutect2, varscan2
- POLR1A | c.2734-1G>A p.X912_splice | Splice Site (SNP) | VAF 13/41 reads (32%) | catalogued as COSV99807463; called by muse, mutect2, varscan2
- POTEF | c.2645G>T p.G882V | Missense Mutation (SNP) | VAF 39/95 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100664467; called by muse, mutect2, varscan2
- PPFIA2 | c.175G>T p.A59S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV100332889; called by muse, mutect2, varscan2
- PPP1R21 | c.1147G>C p.E383Q | Missense Mutation (SNP) | VAF 21/41 reads (51%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.932); catalogued as rs377449879; called by muse, mutect2, varscan2
- PPP2R5B | c.98G>A p.R33H | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.95); catalogued as rs772174283, COSV51214045; called by muse, mutect2, varscan2
- PRB4 | c.398G>T p.R133L | Missense Mutation (SNP) | VAF 54/161 reads (34%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); catalogued as COSV99686470; called by muse, varscan2
- PRDM9 | c.1387T>A p.L463M | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated (0.24); PolyPhen benign (0.084); catalogued as COSV57008458; called by mutect2, varscan2
- PRDM9 | c.1856G>T p.R619L | Missense Mutation (SNP) | VAF 43/195 reads (22%) | SIFT tolerated (0.57); PolyPhen benign (0.009); catalogued as COSV99690299; called by muse, varscan2
- PTGS1 | c.1762G>A p.D588N | Missense Mutation (SNP) | VAF 34/75 reads (45%) | SIFT tolerated (0.32); PolyPhen benign (0.058); catalogued as COSV99793105, COSV99793318; called by muse, mutect2, varscan2
- PTPRR | c.992T>C p.I331T | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs770139589, COSV51751056; called by muse, mutect2, varscan2
- PXMP4 | c.364A>T p.I122F | Missense Mutation (SNP) | VAF 59/81 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99459355; called by muse, mutect2, varscan2
- RAB40B | c.619C>T p.H207Y | Missense Mutation (SNP) | VAF 57/127 reads (45%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.014); catalogued as COSV99483601; called by muse, mutect2, varscan2
- RASGRP3 | c.605C>A p.S202Y | Missense Mutation (SNP) | VAF 73/170 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101274674, COSV67821269; called by muse, mutect2, varscan2
- RCVRN | c.258C>A p.Y86* | Nonsense Mutation (SNP) | VAF 47/123 reads (38%) | catalogued as COSV56841335, COSV99874156; called by muse, mutect2, varscan2
- ROR1 | c.2123G>T p.R708L | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100935149; called by muse, mutect2, varscan2
- RP1 | c.1884G>T p.E628D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.318); catalogued as COSV99607158; called by muse, mutect2, varscan2
- RP1 | c.1885G>T p.A629S | Missense Mutation (SNP) | VAF 16/41 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as COSV99605885; called by muse, mutect2, varscan2
- RSAD2 | c.487G>T p.E163* | Nonsense Mutation (SNP) | VAF 21/51 reads (41%) | catalogued as COSV101149843; called by muse, mutect2, varscan2
- RSAD2 | c.572T>C p.I191T | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781571900, COSV101149846; called by muse, mutect2, varscan2
- RSPO1 | c.350G>A p.G117D | Missense Mutation (SNP) | VAF 41/87 reads (47%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV100740561; called by muse, mutect2, varscan2
- RSPRY1 | c.375G>A p.M125I | Missense Mutation (SNP) | VAF 61/93 reads (66%) | SIFT tolerated (0.07); PolyPhen benign (0.313); catalogued as COSV101070973, COSV68027577; called by muse, mutect2, varscan2
- RTKN2 | c.1468G>T p.A490S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as COSV100189332; called by muse, mutect2, varscan2
- RXFP1 | c.929T>C p.L310P | Missense Mutation (SNP) | VAF 41/83 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100313711; called by muse, mutect2, varscan2
- SASS6 | c.1924C>T p.L642F | Missense Mutation (SNP) | VAF 111/158 reads (70%) | SIFT tolerated (0.72); PolyPhen benign (0.001); catalogued as rs1271730418, COSV99790761; called by muse, mutect2, varscan2
- SATB2 | c.1280T>A p.V427E | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.088); catalogued as COSV99611095; called by muse, mutect2, varscan2
- SCN2A | c.1457G>T p.S486I | Missense Mutation (SNP) | VAF 11/21 reads (52%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.517); catalogued as COSV99331190; called by muse, mutect2, varscan2
- SHANK1 | c.1965-2A>T p.X655_splice | Splice Site (SNP) | VAF 47/103 reads (46%) | catalogued as COSV99520937; called by muse, mutect2, varscan2
- SLC17A6 | c.1012G>T p.E338* | Nonsense Mutation (SNP) | VAF 22/40 reads (55%) | catalogued as COSV99581294; called by muse, mutect2, varscan2
- SLC25A10 | c.534+1G>T p.X178_splice | Splice Site (SNP) | VAF 25/49 reads (51%) | catalogued as COSV100519002; called by muse, mutect2, varscan2
- SLC29A2 | c.73A>T p.T25S | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.241); catalogued as COSV100237080; called by muse, mutect2, varscan2
- SLC4A3 | c.1388G>C p.G463A | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.43); PolyPhen benign (0.026); catalogued as COSV99812743; called by muse, mutect2, varscan2
- SLC4A8 | c.1687C>T p.R563* | Nonsense Mutation (SNP) | VAF 66/180 reads (37%) | catalogued as COSV60657414; called by muse, mutect2, varscan2
- SLC5A11 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 20/37 reads (54%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.654); catalogued as COSV100762748; called by muse, mutect2, varscan2
- SLC5A9 | c.265G>T p.G89C | Missense Mutation (SNP) | VAF 53/127 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99361587; called by muse, mutect2, varscan2
- SLCO1C1 | c.1685C>T p.S562F | Missense Mutation (SNP) | VAF 42/145 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.622); catalogued as COSV56867710; called by muse, mutect2, varscan2
- SNUPN | c.53T>G p.L18R | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.498); catalogued as rs1378659863, COSV100419347; called by muse, mutect2, varscan2
- SNX30 | c.459+1G>T p.X153_splice | Splice Site (SNP) | VAF 20/44 reads (45%) | catalogued as COSV100953839, COSV65293354; called by muse, mutect2, varscan2
- SPANXN1 | c.97G>T p.D33Y | Missense Mutation (SNP) | VAF 27/34 reads (79%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.837); catalogued as COSV65122342, COSV65123446; called by muse, mutect2, varscan2
- SPATS2 | c.544G>A p.G182S | Missense Mutation (SNP) | VAF 52/116 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.613); catalogued as COSV100423460; called by muse, mutect2, varscan2
- SPTA1 | c.3378T>C p.D1126= | Splice Region (SNP) | VAF 58/149 reads (39%) | catalogued as COSV100934770; called by muse, mutect2, varscan2
- SPTA1 | c.134G>A p.R45K | Missense Mutation (SNP) | VAF 24/45 reads (53%) | SIFT tolerated (0.37); PolyPhen benign (0.113); catalogued as rs374697328, CM951193, COSV100934282; called by muse, mutect2, varscan2
- SRGAP2 | c.1859C>T p.A620V (on ENST00000624873 / NM_001170637.4; = p.A621V on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV99832730; called by muse, mutect2, varscan2
- ST18 | c.1280G>A p.R427H | Missense Mutation (SNP) | VAF 33/202 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs745818812, COSV99389276; called by muse, mutect2, varscan2
- STK10 | c.1987G>T p.E663* | Nonsense Mutation (SNP) | VAF 43/60 reads (72%) | catalogued as COSV99451320; called by muse, mutect2, varscan2
- STON1-GTF2A1L | c.2471C>T p.P824L | Missense Mutation (SNP) | VAF 28/86 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100561750, COSV100561773; called by muse, mutect2, varscan2
- TAF1L | c.2365G>T p.G789C | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as COSV99644522; called by muse, mutect2, varscan2
- TAFA1 | c.197A>G p.K66R | Missense Mutation (SNP) | VAF 24/34 reads (71%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.677); catalogued as COSV101524422, COSV72040166; called by muse, mutect2, varscan2
- TARBP1 | c.1982A>T p.N661I | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0.05); PolyPhen benign (0.025); catalogued as COSV99241495; called by muse, mutect2
- TCIRG1 | c.2411A>T p.H804L | Missense Mutation (SNP) | VAF 45/94 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV99693306; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2533G>T p.A845S | Missense Mutation (SNP) | VAF 43/94 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.059); catalogued as COSV99305007; called by muse, mutect2, varscan2
- THSD1 | c.205A>T p.N69Y | Missense Mutation (SNP) | VAF 28/44 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99318851; called by muse, mutect2, varscan2
- THSD7B | c.3892T>C p.C1298R (on ENST00000272643; = p.C1296R on NM_001316349.2) | Missense Mutation (SNP) | VAF 38/89 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99748944; called by muse, mutect2, varscan2
- TICRR | c.2617C>T p.L873F | Missense Mutation (SNP) | VAF 5/13 reads (38%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.992); catalogued as COSV99176307; called by muse, mutect2, varscan2
- TIGAR | c.455A>C p.Q152P | Missense Mutation (SNP) | VAF 12/25 reads (48%) | SIFT tolerated (0.15); PolyPhen benign (0.012); catalogued as COSV99463576; called by muse, mutect2, varscan2
- TJP1 | c.4836A>T p.K1612N | Missense Mutation (SNP) | VAF 40/79 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.046); catalogued as COSV100632622; called by muse, mutect2, varscan2
- TLE4 | c.1412G>C p.G471A | Missense Mutation (SNP) | VAF 49/129 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.51); catalogued as COSV54627210, COSV99511861; called by muse, mutect2, varscan2
- TLL1 | c.2143G>A p.D715N | Missense Mutation (SNP) | VAF 42/126 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99286955; called by muse, mutect2, varscan2
- TLL2 | c.272C>A p.T91K | Missense Mutation (SNP) | VAF 78/199 reads (39%) | SIFT tolerated, low confidence (0.9); PolyPhen benign (0.015); catalogued as COSV100780240; called by muse, mutect2, varscan2
- TMC2 | c.521C>A p.P174H | Missense Mutation (SNP) | VAF 12/37 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100727529; called by muse, mutect2, varscan2
- TMEM26 | c.917T>C p.V306A | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs369431776; called by muse, mutect2, varscan2
- TMEM67 | c.1427C>A p.P476H | Missense Mutation (SNP) | VAF 61/122 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.903); catalogued as COSV100019114; called by muse, mutect2, varscan2
- TMEM74 | c.284C>A p.A95E | Missense Mutation (SNP) | VAF 36/102 reads (35%) | SIFT tolerated (0.22); PolyPhen benign (0.009); catalogued as COSV99865620; called by muse, mutect2, varscan2
- TNNI3K | c.2326A>T p.R776W | Missense Mutation (SNP) | VAF 59/150 reads (39%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.841); catalogued as COSV99631436; called by muse, mutect2, varscan2
- TOM1L1 | c.649C>T p.R217* | Nonsense Mutation (SNP) | VAF 21/156 reads (13%) | catalogued as rs771053348, COSV61946938; called by muse, mutect2, varscan2
- TREM1 | c.272A>T p.H91L | Missense Mutation (SNP) | VAF 40/50 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV99776165; called by muse, mutect2, varscan2
- TRIM21 | c.823G>T p.V275L | Missense Mutation (SNP) | VAF 25/62 reads (40%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.675); catalogued as COSV99587649; called by muse, mutect2, varscan2
- TRIM6 | c.193C>A p.P65T | Missense Mutation (SNP) | VAF 15/33 reads (45%) | SIFT tolerated (0.45); PolyPhen benign (0.138); catalogued as COSV99546312; called by muse, mutect2, varscan2
- TRIP11 | c.1400C>T p.S467L | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.12); PolyPhen benign (0.006); catalogued as COSV50932239, COSV99970585; called by muse, mutect2, varscan2
- TRMT10B | c.610C>T p.P204S | Missense Mutation (SNP) | VAF 84/212 reads (40%) | SIFT tolerated (0.1); PolyPhen benign (0.241); catalogued as COSV99955987; called by muse, mutect2, varscan2
- TRPC5 | c.401C>T p.T134M | Missense Mutation (SNP) | VAF 43/47 reads (91%) | SIFT tolerated (0.08); PolyPhen benign (0.302); catalogued as rs778578106, COSV99460502; called by muse, mutect2, varscan2
- TRPV2 | c.1397T>G p.I466R | Missense Mutation (SNP) | VAF 72/183 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.601); catalogued as COSV100641184, COSV58429128; called by muse, mutect2, varscan2
- TTN | c.17455C>G p.R5819G (on ENST00000591111; = p.R4892G on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/50 reads (46%) | PolyPhen benign (0.04); catalogued as COSV100607456; called by muse, mutect2, varscan2
- TTN | c.8592C>A p.Y2864* (on ENST00000591111; = p.Y2818* on NM_003319.4) | Nonsense Mutation (SNP) | VAF 82/155 reads (53%) | catalogued as COSV100607462; called by muse, mutect2, varscan2
- TXNDC16 | c.1252+2T>G p.X418_splice | Splice Site (SNP) | VAF 31/37 reads (84%) | catalogued as COSV99909108; called by muse, mutect2, varscan2
- UBAP2 | c.1186C>T p.Q396* | Nonsense Mutation (SNP) | VAF 65/158 reads (41%) | catalogued as COSV100671245; called by muse, mutect2, varscan2
- UBR1 | c.4523A>T p.Y1508F | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.018); catalogued as COSV99317078; called by muse, mutect2, varscan2
- UGT2A3 | c.156G>T p.E52D | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.174); catalogued as COSV99279654, COSV99279768; called by muse, mutect2, varscan2
- USP29 | c.2281C>A p.Q761K | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.626); catalogued as COSV99518000; called by muse, varscan2
- VMP1 | c.404T>A p.L135Q | Missense Mutation (SNP) | VAF 35/82 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV99230265; called by muse, mutect2, varscan2
- VPS45 | c.1519A>T p.I507F | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV100964888; called by muse, mutect2, varscan2
- WDR17 | c.107C>T p.A36V | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99707423; called by muse, mutect2, varscan2
- WDR64 | c.2914G>C p.A972P | Missense Mutation (SNP) | VAF 64/121 reads (53%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV100843740; called by muse, mutect2, varscan2
- XIRP2 | c.952A>G p.R318G (on ENST00000628543; = p.R493G on NM_152381.6) | Missense Mutation (SNP) | VAF 16/36 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99741851; called by muse, varscan2
- ZBBX | c.955G>T p.E319* | Nonsense Mutation (SNP) | VAF 14/41 reads (34%) | catalogued as COSV100283839, COSV56786622; called by muse, mutect2, varscan2
- ZBBX | c.954G>T p.M318I | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.062); catalogued as COSV100283840, COSV56786639; called by muse, mutect2, varscan2
- ZC3H11A | c.91A>G p.I31V | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as rs138840191; called by muse, mutect2, varscan2
- ZC3H13 | c.4469C>T p.P1490L (on ENST00000242848 / NM_001330565.2; = p.P1491L on NM_015070.6) | Missense Mutation (SNP) | VAF 155/214 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.395); catalogued as COSV99667980; called by muse, mutect2, varscan2
- ZFAND4 | c.1196G>T p.G399V | Missense Mutation (SNP) | VAF 38/81 reads (47%) | SIFT deleterious (0.03); PolyPhen benign (0.01); catalogued as COSV100762957; called by muse, mutect2, varscan2
- ZFHX4 | c.8213C>A p.T2738N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.77); catalogued as rs1480771480, COSV99261649; called by muse, mutect2, varscan2
- ZGRF1 | c.6112G>C p.G2038R | Missense Mutation (SNP) | VAF 29/76 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV101500600; called by muse, mutect2, varscan2
- ZKSCAN8 | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 27/31 reads (87%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs745845523, COSV100362881; called by muse, mutect2, varscan2
- ZNF208 | c.1080G>T p.K360N | Missense Mutation (SNP) | VAF 10/26 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101236997; called by muse, mutect2, varscan2
- ZNF385D | c.133G>T p.A45S | Missense Mutation (SNP) | VAF 32/46 reads (70%) | SIFT tolerated (1); PolyPhen probably damaging (0.935); catalogued as COSV55767885; called by muse, mutect2, varscan2
- ZNF543 | c.1788A>T p.E596D | Missense Mutation (SNP) | VAF 35/78 reads (45%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.318); catalogued as COSV100386735; called by muse, mutect2, varscan2
- ZNF649 | c.1319T>C p.F440S | Missense Mutation (SNP) | VAF 112/235 reads (48%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100030971; called by muse, mutect2, varscan2
- ZNF658 | c.797G>A p.R266K | Missense Mutation (SNP) | VAF 69/186 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs560970467; called by muse, mutect2, varscan2
- ZNF770 | c.1150A>T p.T384S | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT tolerated (0.27); PolyPhen benign (0.01); catalogued as COSV100695910; called by muse, mutect2, varscan2
- ZNF808 | c.1688C>G p.A563G | Missense Mutation (SNP) | VAF 41/123 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100707887; called by muse, mutect2, varscan2
- ZNRF4 | c.592C>A p.H198N | Missense Mutation (SNP) | VAF 81/214 reads (38%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.611); catalogued as COSV99706472; called by muse, mutect2, varscan2
- ZRANB3 | c.1172G>T p.R391L | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99923363; called by muse, mutect2, varscan2
- ATR | c.289_290del p.I97* | Frame Shift Del (DEL) | VAF 30/99 reads (30%) | called by mutect2, pindel, varscan2
- CEP70 | c.1688dup p.A565Sfs*7 | Frame Shift Ins (INS) | VAF 17/58 reads (29%) | called by mutect2, pindel, varscan2
- CES1 | c.430C>A p.L144M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.912); called by muse, varscan2
- CYFIP1 | c.2279G>C p.R760T | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- FRG2 | c.473G>C p.R158P | Missense Mutation (SNP) | VAF 67/165 reads (41%) | SIFT deleterious (0.04); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- GPATCH2 | c.336del p.D113Ifs*10 | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- IGHE | c.976G>T p.V326F | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IGHV1-24 | c.137A>T p.Y46F | Missense Mutation (SNP) | VAF 147/703 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- IGKV2D-24 | c.310G>A p.E104K | Missense Mutation (SNP) | VAF 97/242 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- KMT2D | c.5303dup p.A1770Cfs*18 | Frame Shift Ins (INS) | VAF 23/71 reads (32%) | called by mutect2, pindel, varscan2
- LPCAT3 | c.549_556del p.L184Sfs*32 | Frame Shift Del (DEL) | VAF 10/40 reads (25%) | called by mutect2, pindel, varscan2
- PAX3 | c.1126_1136delinsGTGG p.P376Vfs*3 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by pindel, varscan2*
- SCX | c.434C>T p.S145F | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious (0.02); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- USP36 | c.3258del p.K1086Nfs*25 | Frame Shift Del (DEL) | VAF 18/61 reads (30%) | called by mutect2, pindel, varscan2
- ACAP1 | c.352C>A p.R118= | Silent (SNP) | VAF 39/110 reads (35%) | catalogued as COSV99341613; called by muse, mutect2, varscan2
- ADCY8 | c.3288G>C p.V1096= | Silent (SNP) | VAF 74/199 reads (37%) | catalogued as COSV99651793; called by muse, mutect2, varscan2
- ADGRL4 | c.237A>G p.E79= | Silent (SNP) | VAF 24/52 reads (46%) | catalogued as COSV100875871; called by muse, mutect2, varscan2
- AFG1L | c.99C>G p.L33= | Silent (SNP) | VAF 36/36 reads (100%) | called by muse, mutect2, varscan2
- ANO6 | c.1707A>T p.I569= | Silent (SNP) | VAF 47/97 reads (48%) | catalogued as COSV100262943, COSV57662197; called by muse, mutect2, varscan2
- ARHGAP11A | c.1371T>C p.Y457= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs1171420755, COSV100853226; called by muse, mutect2, varscan2
- ASB18 | c.54G>A p.K18= | Silent (SNP) | VAF 31/101 reads (31%) | catalogued as COSV101293591; called by muse, mutect2, varscan2
- BCLAF1 | c.411G>A p.R137= | Silent (SNP) | VAF 4/37 reads (11%) | catalogued as rs766469433, COSV100786381; called by muse, mutect2, varscan2
- BIN1 | c.684G>T p.P228= (on ENST00000316724 / NM_001320642.1; = p.P197= on NM_004305.4) | Silent (SNP) | VAF 24/75 reads (32%) | catalogued as COSV52121662, COSV99387874; called by muse, mutect2, varscan2
- BPIFB3 | c.120C>T p.G40= | Silent (SNP) | VAF 24/34 reads (71%) | catalogued as COSV64958407; called by muse, mutect2, varscan2
- BRINP3 | c.153G>A p.K51= | Silent (SNP) | VAF 15/40 reads (38%) | catalogued as rs1558301991, COSV100818656; called by muse, mutect2, varscan2
- C19orf57 | c.807C>T p.P269= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV100694683; called by muse, mutect2, varscan2
- C1orf87 | c.648T>A p.S216= | Silent (SNP) | VAF 22/43 reads (51%) | catalogued as COSV100967022; called by muse, mutect2, varscan2
- C20orf194 | c.1686T>C p.V562= | Silent (SNP) | VAF 9/26 reads (35%) | catalogued as COSV99330616; called by muse, mutect2, varscan2
- CACNG3 | c.339G>T p.T113= | Silent (SNP) | VAF 26/64 reads (41%) | catalogued as rs773149814, COSV50089370; called by muse, mutect2, varscan2
- CBLB | c.648A>G p.L216= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as COSV99913269; called by muse, mutect2, varscan2
- CD247 | c.186C>T p.P62= | Silent (SNP) | VAF 26/82 reads (32%) | catalogued as rs769695112, COSV100758337; called by muse, mutect2, varscan2
- CDHR3 | c.2061C>T p.I687= | Silent (SNP) | VAF 178/218 reads (82%) | catalogued as COSV100488227; called by muse, mutect2, varscan2
- CSMD1 | c.1323C>G p.V441= (on ENST00000520002; = p.V440= on NM_033225.6) | Silent (SNP) | VAF 44/135 reads (33%) | catalogued as COSV101219670, COSV68257855; called by muse, mutect2, varscan2
- CSMD3 | c.555C>A p.P185= | Silent (SNP) | VAF 25/73 reads (34%) | catalogued as COSV99831999; called by muse, mutect2, varscan2
- CYP26B1 | c.1092G>T p.L364= | Silent (SNP) | VAF 44/124 reads (35%) | catalogued as COSV50011001, COSV50012722; called by muse, mutect2, varscan2
- CYP4F2 | c.108C>T p.A36= | Silent (SNP) | VAF 41/110 reads (37%) | catalogued as COSV99171071; called by muse, mutect2, varscan2
- DAB1 | c.342C>A p.S114= | Silent (SNP) | VAF 22/59 reads (37%) | catalogued as COSV100139916; called by muse, mutect2, varscan2
- DBH | c.639C>A p.T213= | Silent (SNP) | VAF 14/33 reads (42%) | catalogued as COSV55042495, COSV99708017; called by muse, mutect2, varscan2
- DNAAF2 | c.2397T>C p.P799= | Silent (SNP) | VAF 37/51 reads (73%) | catalogued as COSV100023504; called by muse, mutect2, varscan2
- FER | c.2169C>T p.P723= | Silent (SNP) | VAF 23/38 reads (61%) | catalogued as COSV99812492; called by muse, mutect2, varscan2
- FGR | c.1260C>T p.F420= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100925812; called by muse, mutect2
- FMN2 | c.3657T>A p.P1219= | Silent (SNP) | VAF 23/52 reads (44%) | catalogued as rs762946862, COSV100144628; called by muse, mutect2, varscan2
- GLYAT | c.642G>A p.G214= | Silent (SNP) | VAF 27/76 reads (36%) | catalogued as rs1361900668, COSV99557277; called by muse, mutect2, varscan2
- HTR2A | c.300C>A p.S100= | Silent (SNP) | VAF 56/78 reads (72%) | catalogued as COSV101096669; called by muse, mutect2, varscan2
- IARS1 | c.3249C>G p.V1083= | Silent (SNP) | VAF 34/76 reads (45%) | catalogued as COSV100986694; called by muse, mutect2, varscan2
- IGKV1-6 | c.36C>A p.L12= | Silent (SNP) | VAF 125/284 reads (44%) | called by muse, mutect2, varscan2
- IGLV3-25 | c.81C>G p.P27= | Silent (SNP) | VAF 29/72 reads (40%) | catalogued as rs1252984132; called by muse, mutect2, varscan2
- IL7R | c.225G>T p.G75= | Silent (SNP) | VAF 21/84 reads (25%) | catalogued as COSV100286206; called by muse, mutect2, varscan2
- ITGAL | c.42G>T p.L14= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV100776218; called by muse, mutect2, varscan2
- KCNA4 | c.855C>A p.P285= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV100068847, COSV100069000, COSV60252599; called by muse, mutect2, varscan2
- KCNJ12 | c.690G>A p.A230= | Silent (SNP) | VAF 7/19 reads (37%) | catalogued as rs782751588, COSV59163144, COSV59171041; called by muse, mutect2, varscan2
- KCNJ4 | c.861G>T p.V287= | Silent (SNP) | VAF 18/48 reads (38%) | catalogued as COSV100341148; called by muse, mutect2, varscan2
- KDM5A | c.4263G>T p.R1421= | Silent (SNP) | VAF 35/83 reads (42%) | catalogued as COSV101238753; called by muse, mutect2, varscan2
- KIF16B | c.246C>G p.L82= | Silent (SNP) | VAF 17/46 reads (37%) | catalogued as COSV100734160, COSV61715878; called by muse, mutect2, varscan2
- KIR2DL3 | c.93C>T p.L31= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as rs1568936560; called by muse, mutect2, varscan2
- KMT2D | c.2766G>A p.E922= | Silent (SNP) | VAF 25/104 reads (24%) | catalogued as COSV99980460; called by muse, mutect2, varscan2
- KMT5C | c.1341G>T p.V447= | Silent (SNP) | VAF 8/12 reads (67%) | catalogued as COSV99726159; called by muse, mutect2, varscan2
- LARS1 | c.3408C>A p.T1136= (on ENST00000394434 / NM_020117.11; = p.T1109= on NM_016460.3) | Silent (SNP) | VAF 31/43 reads (72%) | catalogued as COSV99198570; called by muse, mutect2, varscan2
- LILRB5 | c.822G>C p.G274= | Silent (SNP) | VAF 28/77 reads (36%) | catalogued as rs1159559967, COSV100300298; called by muse, mutect2, varscan2
- MAGEL2 | c.2124G>T p.L708= | Silent (SNP) | VAF 5/9 reads (56%) | catalogued as COSV100045887; called by muse, mutect2
- MAMLD1 | c.1662C>G p.P554= | Silent (SNP) | VAF 85/104 reads (82%) | catalogued as COSV99475851; called by muse, varscan2
- MAPK8IP1 | c.1434G>T p.G478= | Silent (SNP) | VAF 26/72 reads (36%) | catalogued as COSV99571357; called by muse, mutect2, varscan2
- MDGA2 | c.2211T>A p.I737= (on ENST00000399232 / NM_001113498.2; = p.I439= on NM_182830.4) | Silent (SNP) | VAF 39/48 reads (81%) | catalogued as COSV100636924; called by muse, mutect2, varscan2
- MFGE8 | c.840G>T p.A280= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as rs202157001, COSV51556183, COSV51557176; called by muse, mutect2, varscan2
- MINAR1 | c.31T>C p.L11= | Silent (SNP) | VAF 5/23 reads (22%) | catalogued as COSV100548841; called by muse, mutect2, varscan2
- MORC1 | c.249T>C p.F83= | Silent (SNP) | VAF 36/90 reads (40%) | catalogued as COSV99225835; called by muse, mutect2, varscan2
- MUC16 | c.20055T>C p.A6685= | Silent (SNP) | VAF 66/180 reads (37%) | catalogued as COSV101199518; called by muse, mutect2, varscan2
- NFE2 | c.402G>C p.G134= | Silent (SNP) | VAF 56/121 reads (46%) | catalogued as COSV100380728; called by muse, mutect2, varscan2
- NLRP11 | c.393A>T p.I131= | Silent (SNP) | VAF 17/50 reads (34%) | catalogued as COSV100789712; called by muse, mutect2, varscan2
- NR3C2 | c.2667G>A p.Q889= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as COSV100678944; called by muse, mutect2, varscan2
- OR12D2 | c.547C>T p.L183= | Silent (SNP) | VAF 116/131 reads (89%) | catalogued as COSV101011233, COSV101011319; called by muse, mutect2, varscan2
- OR2AK2 | c.819G>A p.A273= | Silent (SNP) | VAF 12/44 reads (27%) | catalogued as rs764697677, COSV100823802, COSV63559112; called by muse, mutect2
- OR4N2 | c.585G>A p.V195= | Silent (SNP) | VAF 70/92 reads (76%) | catalogued as COSV60049743; called by muse, mutect2, varscan2
- OR5L1 | c.174C>A p.P58= | Silent (SNP) | VAF 99/319 reads (31%) | catalogued as COSV100450019, COSV100450340; called by muse, mutect2, varscan2
- OR5L2 | c.432G>A p.L144= | Silent (SNP) | VAF 89/266 reads (33%) | catalogued as COSV101004303; called by muse, mutect2, varscan2
- OR6B2 | c.780C>T p.V260= | Silent (SNP) | VAF 13/38 reads (34%) | catalogued as COSV99401387; called by muse, mutect2, varscan2
- OR6N2 | c.669G>T p.G223= | Silent (SNP) | VAF 5/20 reads (25%) | catalogued as rs771360819, COSV100210082; called by muse, mutect2, varscan2
- OR6Q1 | c.630G>T p.V210= | Silent (SNP) | VAF 60/105 reads (57%) | catalogued as COSV100109802; called by muse, mutect2, varscan2
- OR8D1 | c.729T>C p.S243= | Silent (SNP) | VAF 16/25 reads (64%) | catalogued as rs1449804282, COSV100766617; called by muse, mutect2, varscan2
- OR8J1 | c.420C>G p.L140= | Silent (SNP) | VAF 38/122 reads (31%) | catalogued as COSV100274972; called by muse, mutect2, varscan2
- PCDH11Y | c.3705C>A p.A1235= | Silent (SNP) | VAF 40/48 reads (83%) | catalogued as COSV99291203; called by muse, mutect2, varscan2
- PFDN5 | c.300G>A p.K100= | Silent (SNP) | VAF 103/295 reads (35%) | catalogued as COSV99229209; called by muse, mutect2, varscan2
- PGK2 | c.819A>T p.A273= | Silent (SNP) | VAF 95/114 reads (83%) | catalogued as COSV100505435; called by muse, mutect2, varscan2
- PKHD1L1 | c.5476C>T p.L1826= | Silent (SNP) | VAF 17/61 reads (28%) | catalogued as COSV101005995; called by muse, mutect2, varscan2
- PLEC | c.9042G>T p.T3014= (on ENST00000322810 / NM_201380.4; = p.T2904= on NM_000445.5) | Silent (SNP) | VAF 28/74 reads (38%) | catalogued as COSV100513140; called by muse, mutect2, varscan2
- PLSCR5 | c.444C>T p.Y148= | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs1332897738, COSV101494482, COSV71649341; called by muse, mutect2, varscan2
- PON3 | c.51C>A p.V17= | Silent (SNP) | VAF 120/140 reads (86%) | catalogued as COSV99672404; called by muse, mutect2, varscan2
- PRB4 | c.519C>A p.S173= | Silent (SNP) | VAF 74/176 reads (42%) | catalogued as COSV54396889, COSV99686468; called by muse, varscan2
- PYY | c.293G>A p.*98= | Silent (SNP) | VAF 21/66 reads (32%) | catalogued as COSV100778928; called by muse, mutect2, varscan2
- RBM4B | c.99C>T p.I33= | Silent (SNP) | VAF 36/136 reads (26%) | catalogued as rs1179342463, COSV100026422; called by muse, mutect2, varscan2
- RHPN2 | c.1182A>T p.T394= | Silent (SNP) | VAF 10/71 reads (14%) | catalogued as COSV99577430; called by muse, mutect2, varscan2
- RIPK3 | c.1167A>C p.S389= | Silent (SNP) | VAF 74/103 reads (72%) | catalogued as COSV99353154; called by muse, mutect2, varscan2
- RTKN | c.648A>G p.K216= (on ENST00000272430 / NM_001015055.2; = p.K203= on NM_033046.2) | Silent (SNP) | VAF 19/54 reads (35%) | catalogued as COSV99269546; called by muse, mutect2, varscan2
- RTN1 | c.1968T>A p.P656= | Silent (SNP) | VAF 25/32 reads (78%) | catalogued as COSV99955370; called by muse, mutect2, varscan2
- SLC2A13 | c.1779T>C p.C593= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV99786355; called by muse, mutect2, varscan2
- SLC6A19 | c.375G>A p.V125= | Silent (SNP) | VAF 41/60 reads (68%) | catalogued as COSV100443397; called by muse, mutect2, varscan2
- SNUPN | c.54G>A p.L18= | Silent (SNP) | VAF 26/58 reads (45%) | catalogued as COSV100419345; called by muse, mutect2, varscan2
- SPEG | c.3381C>A p.G1127= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV100404200; called by muse, mutect2, varscan2
- SZT2 | c.1641G>A p.Q547= | Silent (SNP) | VAF 14/37 reads (38%) | catalogued as rs1402431578, COSV100987173; called by muse, mutect2, varscan2
- TCTE3 | c.555C>A p.S185= | Silent (SNP) | VAF 119/134 reads (89%) | catalogued as COSV100825403; called by muse, mutect2, varscan2
- TGFB1I1 | c.48G>A p.S16= | Silent (SNP) | VAF 8/58 reads (14%) | catalogued as rs1021326121, COSV62359276; called by muse, mutect2, varscan2
- TMEM108 | c.627G>A p.Q209= | Silent (SNP) | VAF 20/52 reads (38%) | catalogued as COSV100418687; called by muse, mutect2, varscan2
- TMPRSS9 | c.477G>A p.L159= (on ENST00000648592; = p.L125= on NM_182973.2) | Silent (SNP) | VAF 10/26 reads (38%) | catalogued as COSV100211296; called by muse, mutect2, varscan2
- WDFY3 | c.5436T>C p.D1812= | Silent (SNP) | VAF 17/56 reads (30%) | catalogued as COSV99883106; called by muse, mutect2, varscan2
- ZFHX4 | c.5727C>A p.A1909= | Silent (SNP) | VAF 4/8 reads (50%) | catalogued as COSV50705303; called by muse, mutect2, varscan2
- ZNF292 | c.6393G>A p.L2131= | Silent (SNP) | VAF 43/50 reads (86%) | catalogued as COSV100370229; called by muse, mutect2, varscan2
- ZNF407 | c.4614C>T p.V1538= | Silent (SNP) | VAF 43/65 reads (66%) | catalogued as COSV99995462; called by muse, mutect2, varscan2
- ZNF582 | c.1329T>C p.V443= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100018640; called by muse, mutect2, varscan2
- ADGRA1 | chr10:133085031 G>T | 5'Flank (SNP) | VAF 51/104 reads (49%) | catalogued as rs779531323, COSV100811016; called by muse, mutect2, varscan2
- CCHCR1 | c.-51-403G>A | Intron (SNP) | VAF 41/48 reads (85%) | catalogued as COSV100883855; called by muse, mutect2, varscan2
- DCHS2 | n.4423G>T | RNA (SNP) | VAF 59/159 reads (37%) | catalogued as COSV100601613; called by muse, mutect2, varscan2
- DEFB119 | c.61+1334G>C | Intron (SNP) | VAF 9/59 reads (15%) | catalogued as COSV100190753, COSV59267802; called by muse, mutect2, varscan2
- DNMT3A | c.-178+13732C>A | Intron (SNP) | VAF 6/18 reads (33%) | catalogued as COSV99261799; called by muse, mutect2, varscan2
- DPP6 | c.627+21091G>C | Intron (SNP) | VAF 173/204 reads (85%) | catalogued as COSV100124855; called by muse, mutect2, varscan2
- FOLH1B | n.968C>T | RNA (SNP) | VAF 61/124 reads (49%) | catalogued as rs1467923508; called by muse, mutect2, varscan2
- MIR520G | n.28C>G | RNA (SNP) | VAF 30/91 reads (33%) | called by muse, mutect2, varscan2
- NR6A1 | c.142+40777C>T | Intron (SNP) | VAF 17/36 reads (47%) | catalogued as COSV100748513; called by muse, mutect2, varscan2
- NRXN1 | c.772+1090G>C | Intron (SNP) | VAF 6/15 reads (40%) | catalogued as COSV101277499; called by muse, mutect2, varscan2
- PYY3 | n.99C>T | RNA (SNP) | VAF 6/9 reads (67%) | catalogued as rs782506237; called by muse, mutect2, varscan2
- REG1A | c.-1C>A | 5'UTR (SNP) | VAF 40/71 reads (56%) | catalogued as COSV99286768; called by muse, mutect2, varscan2
- SNAP25 | c.164-186G>C | Intron (SNP) | VAF 24/54 reads (44%) | catalogued as COSV99654772; called by muse, mutect2, varscan2
- TAFA5 | c.113-70072C>A | Intron (SNP) | VAF 16/40 reads (40%) | catalogued as COSV100385861; called by muse, mutect2, varscan2
- TTN | c.10361-4962G>A | Intron (SNP) | VAF 31/61 reads (51%) | catalogued as COSV100607458; called by muse, mutect2, varscan2
- TTN | c.10303+1436C>A | Intron (SNP) | VAF 98/221 reads (44%) | catalogued as COSV100607460; called by muse, mutect2, varscan2
- XIRP2 | c.*934C>A | 3'UTR (SNP) | VAF 20/53 reads (38%) | catalogued as COSV54739003, COSV99741856; called by muse, mutect2, varscan2
